CCDI case PBCLTH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/da72923d-d0a5-4173-8059-4d73d975de04

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Synovial sarcoma, NOS: ICD-O-3 morphology code: 9040/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 6.9 years (2,502 days).

Biospecimens (3 samples)
- Sample 0DVKDJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVKDT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVKEC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
